Surgical pathology report (de-identified scan), TCGA case TCGA-D8-A141, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Greater Poland Cancer Center, specimen TCGA-D8-A141-01A (Primary Tumor).

[page 1 of 2]
8500/3
Infiltrating duct carcinoma, NOS
Site: breast, NOS
C50.9
11/22/10

page 1 / 2

Department of Cancer Pathology

copy No.

Date:

Examination: Histopathological examination

Examination No.:

Patient: f PESEL: Age: Gender: F

Material: Total organ resection – right breast
Unit in charge:

Physician in charge:
Material collected on: Material received on:
Expected time of examination: up to
Clinical diagnosis:

Examination performed on:

Results of immunohistochemical examination:

Estrogen receptors in neoplastic cell nuclei not found. Progesterone receptors found in 75% of neoplastic cell nuclei. HER2 protein stained with HercepTest™ by DAKO. Negative reaction in invasive carcinoma cells (Score = 1+)

Compliance validated by:

Examination performed on:

Macroscopic description:

✓ Right breast, sized 22 x 15 x 4cm, removed along with axillary tissues sized 9 x 7 x 2 cm and a skin flap of 13 x 7.5 cm. Tumour sized 1.5 x 1.5 x 1.5 cm found on the boundary of inner quadrants, placed 5.0 cm from the upper edge, 0.7 cm from the base and 0.6 cm from the skin.

Microscopic description:

✓ Carcinoma ductale invasivum - NHG2 (3+2+1/2 mitoses/10 HPF - visual area 0.55mm). Numerous focuses of carcinoma ductale in situ (DCIS) found within tumour (cribrate type, with high nuclear atypia and comedo necrosis and calcifications, 20% of the tumour). Reactio lymphocytaria peritumoralis.

Glandular tissue showing lesions of the type mastopathia fibrosa et cystica. Axillary lymph nodes: Micrometastases carcinomatosae in lymphonodo (No I/XV).

Histopathological diagnosis:

Carcinoma ductale invasivum et ductale in situ mammae dextrae. Micrometastases carcinomatosae in lymphonodo axillae (No I/XV). (NHG2; pT1c; pN1(mi).

Compliance validated by:

Review	Yes	No
Qualification Primary Listed		
Site Specimen		

[page 2 of 2]
Examination performed on:

Examination: Histopathological examination

page 2 / 2

Examination No.:

Patient:

PESEL:

Gender: F

Examination performed on:

Complementary diagnosis:

Following reassessment of receptor status on selected material:

Estrogen receptors found in 75% of neoplastic cell nuclei. Progesterone receptors found in 75% of neoplastic cell nuclei. HER2 protein stained with HercepTest™ by DAKO. Negative reaction in invasive carcinoma cells (Score = 1+)

DUCTAL INVASIVE CARCINOMA OF THE RIGHT BREAST
MICROMETASTASIS IN ONE AXILLARY LYMPH NODE !

Compliance validated by:

Source: NCI Genomic Data Commons file f8926d41-c076-4982-af26-61d4ae291ee5 (TCGA-D8-A141.AA6F84C8-D0B4-446F-A8A7-8CE7F9D07ECF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).